Somatic mutation profile of tumor specimen TARGET-40-NAAHBP-01A (aliquot TARGET-40-NAAHBP-01A-01D) from TARGET case TARGET-40-NAAHBP, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.0 years (4,747 days).
Specimen TARGET-40-NAAHBP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14c23027-a5d5-4dda-b09c-672b3138958e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHBP-10A (Blood Derived Normal), aliquot TARGET-40-NAAHBP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/251cfce9-36ad-45ac-9f7c-290082ed8b13

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.2801C>G p.P934R | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221235046; called by muse, mutect2, varscan2
- SLIT3 | c.3662G>T p.S1221I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- DGKG | c.1614C>A p.G538= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- MSN | c.1002G>A p.E334= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs113359990, COSV64303140; called by muse, mutect2, varscan2
- PKHD1 | c.5013C>G p.T1671= | Silent (SNP) | VAF 26/235 reads (11%) | catalogued as COSV61860782; called by muse, mutect2, varscan2
